Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8DZ, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8DZ-01A (Primary Tumor).

Collect date.
(MM/DD/YYYY)

ICD-O-3
Adenocarcinoma, signet ring cell
8490/3
Site: Gastric antrum c16.3
g 11/23/13

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

- Product of total gastrectomy:

Adenocarcinoma:

Location: gastric antrum

Classification Borman

Standard histological observed:

Mucosecretor mucocellular with "signet ring" cells

Histologic grade III - poorly differentiated

Lauren's Classification: diffuse pattern

Measure of the greatest dimension: 11.0 cm

Ulceration: Present

Involvement of:

Adjacent adipose tissue

Type of tumor invasion: spiculated

Inflammatory reaction: discrete.

Tumor implantation in peri-visceral adipose tissue: Not detected

Proximal margin: involved by neoplasia

Distal margin: uninvolved by neoplasia

Neural infiltration: Present

Lymphatic vascular invasion: Present

Blood vascular invasion: Not detected

Greater omentum: involved by neoplasia

Lymph nodes of lesser curvature:

Metastasis of adenocarcinoma with capsule perforation: (12/12).

Lymph nodes of greater curvature:

Metastasis of adenocarcinoma with capsule perforation: (6/8).

Source: NCI Genomic Data Commons file 6be4894e-9085-45b4-835f-4dc7642cf17e (TCGA-VQ-A8DZ.ABF1CCF2-99C9-4D55-94A2-06E867C5F460.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).